Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7069, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7069-01A (Primary Tumor).

[page 1 of 4]
Patient Name	MRN	Visit Number

Event Date and Time	Procedure Ordered	Status	Ordered By	Specimen #
	Surgical Pathology Report	complete		
Collection				
Accession				
Result Date				
Copath				

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Nck: contents left neck dissection ,level 1-4
2. Oral Cavity:floor of mouth margin
3. Oral Cavity :Deep margin left cheek
4. Oral Cavity:left buccal margin
5. Oral Cavity :Composite resection of left mandible single long anterior double long posterior double short floor of mouth
6. Oral Cavity:Teeth
7. Surgical Waste

DIAGNOSIS

1. Contents of neck dissection, levels I-IV.
Twenty-eight lymph nodes negative for tumour (0/28).
Submandibular gland with focal chronic sialadenitis.
2. Floor of mouth margin.
Negative for carcinoma.
3. Deep margin left cheek.
Negative for carcinoma.
4. Left buccal margin.
Negative for carcinoma.
5. Oral cavity; left mandible; composite resection.
Squamous cell carcinoma, moderately differentiated.
Maximum tumour diameter 2.2 cm.
No lymphovascular invasion.
No perineural invasion.
6. All margins negative for tumor (>0.5 cm).
7. Sections of mandible are pending. An addendum report will follow.
8. Teeth.
Three teeth with no pathologic changes. (Gross examination only)
9. Surgical waste.

[page 2 of 4]
Skin with no pathologic changes. (Gross examination only)

SYNOPTIC DATA

Specimen Type: Resection: Left mandible composite resection
Tumor Site: Oral Cavity
Histologic Type: Squamous cell carcinoma, conventional
Tumor Size: Greatest dimension: 2.2 cm
Histologic Grade: G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent
Perineural Invasion: Absent
Additional Pathologic Findings: None identified
Margins: Margins uninvolved by tumor
Margins uninvolved by tumor - Distance of tumor from closest margin: 0.7 cm
Margins: floor of mouth
pN0: No regional lymph node metastasis for aerodigestive sites
Number of regional lymph nodes examined: 28
Number of regional lymph nodes involved: 0
pMX: Distant metastasis cannot be assessed
*Pathologic Staging is based on AJCC/UICC TNM, [REDACTED] Edition

ELECTRONICALLY VERIFIED BY [REDACTED]

CLINICAL HISTORY

left alveolar scc.

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "contents of left neck dissection levels 1 to 4". It consists of an oriented left neck dissection with dimensions of 13 x 8 x 1.4 cm. The submandibular gland measures 4 x 2 x 1.5 cm and is unremarkable. Multiple lymph nodes ranging from 0.1 to 0.9 cm are identified in multiple levels.

1A submandibular gland

1B level I multiple lymph nodes

1C level II, one lymph node

1D level III, one lymph node

1E level III multiple lymph nodes

1F-1J level IV multiple lymph nodes

[page 3 of 4]
2. The specimen is labeled with the patient's name and as "floor of mouth margins". It consists of a fragment of tissue measuring 2 x 0.2 cm. The specimen is submitted in toto for frozen section.

2A frozen section control

3. The specimen is labeled with the patient's name and as "deep margin left cheek". It consists of a fragment of tissue measuring 0.5 cm. The specimen is submitted in toto for frozen section.

3A frozen section control

4. The specimen is labeled with the patient's name and as "left buccal margin". It consists of a fragment of tissue measuring 1.5 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and as "composite resection of left mandible single long anterior double long posterior double short floor of mouth". It consists of a left lower mandible measuring 9.8 AP x 4.3 SI x 2.4 ML cm. It includes 3 teeth. There is a tumor involving the alveolar mucosa. The tumor measures 2.2 AP x 1.2 SI x 1.4 ML cm. The tumor is raised and congested. The tumor is located at 0.7 cm from the closest floor of mouth margin. The distance to the remaining margins is as follows: 0.9 cm lateral mucosal margin, 1.5 cm anterior mucosal margin, 1.5 cm posterior mucosal margin. Representative sections are submitted.

5A medial floor of mouth margin

5B lateral mucosal margin

5C anterior mucosal margin

5D posterior mucosal margin

5E tumor

5F anterior bone margin (decalcification)

5G posterior bone margin (decalcification)

5H mid mandible and tumor (decalcification)

6. The specimen is labeled with the patient's name and as "teeth". It consists of 3 unremarkable teeth ranging in size from 2 x 0.7 x 0.4 cm to 2.2 x 0.7 x 0.5 cm. No sections are submitted.

7. The specimen is labeled with the patient's name and as "surgical waste". It consists of an unremarkable skin measuring 8.5 x 5 x 2.3 cm. No section is submitted.

QUICK SECTION

2. Floor of mouth (quick section x1): negative for malignancy

3. Deep margin, left cheek (quick section x1): negative for malignancy.

[page 4 of 4]
4. Left buccal margin (quick section x1): negative for malignancy.

Source: NCI Genomic Data Commons file c0e894c3-182f-4eab-9c2a-a61acab13a01 (TCGA-CQ-7069.0AC3981E-4FA7-4240-A678-1171C8693F37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).